Somatic mutation profile of tumor specimen 0DF2CK from CCDI case PBBPSM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain stem; Age at diagnosis: 1.8 years (643 days).
Specimen 0DF2CK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee7ef1b7-3c54-48bd-be38-0b08f2113ad7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DF2DG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/454595d0-46ec-4540-a1ed-54180197675f

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ELAVL1 | c.856G>A p.G286R | Missense Mutation (SNP) | VAF 14/284 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as COSV60968288; called by muse, mutect2
- GABRB1 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 70/1100 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as rs775300084, COSV54979043; called by muse, mutect2
- PRUNE2 | c.2633C>T p.A878V | Missense Mutation (SNP) | VAF 263/668 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV65049065; called by muse, mutect2, varscan2
- TMEM63C | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 33/829 reads (4%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1033761071, COSV53608781; called by muse, mutect2
- ARHGAP31 | c.4103A>C p.D1368A | Missense Mutation (SNP) | VAF 120/586 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2
- TENM3 | c.1639+63C>T | Intron (SNP) | VAF 16/210 reads (8%) | called by muse, mutect2
